CCDI case PBCCYT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2e824551-0b92-48f4-a9e6-8ef93dd63ab3

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (461 days).

Biospecimens (3 samples)
- Sample 0DP4P2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP4PG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP4Q7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
